Somatic mutation profile of tumor specimen C3N-02635-01 (aliquot CPT0182070007) from CPTAC case C3N-02635, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 56.7 years (20,705 days).
Specimen C3N-02635-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f76b3e6-060b-4dbe-b68d-6fa71ee3d1d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02635-31 (Blood Derived Normal), aliquot CPT0182130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c1fb1b5-1605-4df1-a81e-862e73465e9f

The open-access MAF lists 70 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Frame Shift Del 5, Intron 3, Nonsense Mutation 2, 3'UTR 2, Frame Shift Ins 2, Splice Site 2, 3'Flank 1, In Frame Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 31/143 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC5 | c.1600C>A p.Q534K | Missense Mutation (SNP) | VAF 244/586 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55590808; called by muse, mutect2, varscan2
- BAG6 | c.1063A>G p.M355V | Missense Mutation (SNP) | VAF 154/376 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs138038562; called by muse, mutect2, varscan2
- CASP12 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as rs564091554, COSV100998306; called by muse, mutect2, varscan2
- CNTRL | c.3008C>T p.S1003F | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53051349; called by muse, mutect2, varscan2
- DNAH1 | c.3259C>T p.R1087C | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs540247484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.10306C>T p.R3436C | Missense Mutation (SNP) | VAF 229/587 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs774231638, COSV54237891; called by muse, mutect2, varscan2
- EWSR1 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100130981, COSV58422614; called by muse, mutect2, varscan2
- GHR | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs758298128, COSV100051297, COSV50105852; called by muse, mutect2, varscan2
- GRM1 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 113/412 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs777166317, COSV99263755, COSV99264348; called by muse, mutect2, varscan2
- H2BC8 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1561989055; called by muse, mutect2
- HOXD4 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 193/435 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1440241547, COSV60460292; called by muse, mutect2, varscan2
- KCNE5 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 111/411 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1260266181, COSV100927704; called by muse, mutect2, varscan2
- MYO15A | c.3358C>T p.R1120C | Missense Mutation (SNP) | VAF 48/426 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as rs375451997, COSV52760947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIPBL | c.1445_1448del p.R482Nfs*20 | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | catalogued as rs80358382; called by mutect2, pindel, varscan2
- NUP188 | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746583453; called by muse, mutect2, varscan2
- NUTM2F | c.1498C>T p.R500C | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1246236256; called by mutect2, varscan2
- PTEN | c.170del p.L57Wfs*42 | Frame Shift Del (DEL) | VAF 72/120 reads (60%) | catalogued as COSV64290332; called by mutect2, pindel, varscan2
- SIAH3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs200127410, COSV68551773; called by muse, mutect2
- SLTM | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 86/313 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs752863627; called by muse, mutect2, varscan2
- ST6GAL2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 7/155 reads (5%) | PolyPhen probably damaging (0.992); catalogued as rs1171034466, COSV64526226; called by muse, mutect2
- TBC1D10B | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.021); catalogued as rs774831900; called by muse, mutect2
- TBC1D16 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as rs777334677, COSV100188054; called by muse, mutect2, varscan2
- TEX13A | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 64/315 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1300539368; called by muse, mutect2, varscan2
- TRIM29 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 126/303 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.886); catalogued as rs764413015, COSV100531489, COSV59281030; called by muse, mutect2, varscan2
- VCAN | c.4007G>A p.R1336Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs372244245, COSV54098984; called by muse, mutect2, varscan2
- ANO7 | c.592C>T p.Q198* (on ENST00000274979; = p.Q144* on NM_001370694.2) | Nonsense Mutation (SNP) | VAF 102/286 reads (36%) | called by muse, mutect2, varscan2
- CGNL1 | c.2267dup p.E757Rfs*3 | Frame Shift Ins (INS) | VAF 219/628 reads (35%) | called by mutect2, pindel, varscan2
- CNNM1 | c.385G>T p.G129* | Nonsense Mutation (SNP) | VAF 49/163 reads (30%) | called by muse, mutect2, varscan2
- CTCFL | c.289_290del p.M97Efs*26 | Frame Shift Del (DEL) | VAF 162/554 reads (29%) | called by pindel, varscan2
- DMBT1 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 47/653 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- FIP1L1 | c.1784_*3del | Nonstop Mutation (DEL) | VAF 91/336 reads (27%) | called by mutect2, pindel, varscan2
- FOXJ2 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); called by muse, varscan2
- H2BC8 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.17); called by muse, mutect2
- INTS13 | c.2043C>A p.N681K | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IQSEC2 | c.3979C>G p.P1327A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JAM3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 109/350 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KIF13A | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 120/343 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2D | c.13924_13925dup p.T4643Sfs*24 | Frame Shift Ins (INS) | VAF 71/228 reads (31%) | called by mutect2, pindel, varscan2
- LRBA | c.4172del p.N1391Ifs*10 | Frame Shift Del (DEL) | VAF 40/127 reads (31%) | called by mutect2, pindel, varscan2
- MDN1 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- MYH11 | c.3291_3293+14del p.X1097_splice | Splice Site (DEL) | VAF 82/337 reads (24%) | called by mutect2, pindel, varscan2
- NBN | c.968del p.C323Lfs*11 | Frame Shift Del (DEL) | VAF 283/610 reads (46%) | called by mutect2, pindel, varscan2
- PAF1 | c.47+1G>A p.X16_splice | Splice Site (SNP) | VAF 179/444 reads (40%) | called by muse, mutect2, varscan2
- PIK3CB | c.352_369del p.P118_D123del | In Frame Del (DEL) | VAF 32/401 reads (8%) | called by mutect2, pindel
- REM1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLIT2 | c.2374C>A p.L792I | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TP63 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); called by muse, mutect2
- ZFP36L1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 74/102 reads (73%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF579 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CRACD | c.2478C>T p.N826= | Silent (SNP) | VAF 136/321 reads (42%) | called by muse, mutect2, varscan2
- ELAC2 | c.2022C>G p.V674= | Silent (SNP) | VAF 20/616 reads (3%) | catalogued as COSV52393010; called by muse, mutect2
- HCN4 | c.39C>T p.Y13= | Silent (SNP) | VAF 83/371 reads (22%) | called by muse, mutect2, varscan2
- MYH8 | c.3630T>C p.I1210= | Silent (SNP) | VAF 168/443 reads (38%) | called by muse, mutect2, varscan2
- NOL6 | c.417G>T p.V139= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs776646381; called by muse, mutect2, varscan2
- PAF1 | c.802T>C p.L268= | Silent (SNP) | VAF 162/393 reads (41%) | catalogued as rs114633094; called by muse, mutect2, varscan2
- RAD23A | c.855C>T p.N285= | Silent (SNP) | VAF 126/308 reads (41%) | catalogued as rs758550253, COSV57535994; called by muse, mutect2, varscan2
- RAI1 | c.5517C>T p.A1839= | Silent (SNP) | VAF 143/558 reads (26%) | catalogued as rs377747563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCA4 | c.3351G>A p.A1117= | Silent (SNP) | VAF 298/633 reads (47%) | catalogued as rs781587481, COSV60792707; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRL | c.114C>T p.I38= | Silent (SNP) | VAF 141/359 reads (39%) | catalogued as rs201728702, COSV68424238; called by muse, mutect2, varscan2
- TKTL2 | c.1605C>T p.V535= | Silent (SNP) | VAF 101/260 reads (39%) | catalogued as rs1188052793; called by muse, mutect2, varscan2
- TOM1 | c.111C>T p.C37= | Silent (SNP) | VAF 18/408 reads (4%) | catalogued as rs903939191; called by muse, mutect2
- XRCC6 | c.1009C>T p.L337= | Silent (SNP) | VAF 68/174 reads (39%) | called by muse, mutect2, varscan2
- ZFHX4 | c.2790C>A p.L930= | Silent (SNP) | VAF 27/273 reads (10%) | catalogued as COSV51486236; called by muse, mutect2, varscan2
- LDB3 | c.*25G>A | 3'UTR (SNP) | VAF 108/362 reads (30%) | catalogued as rs376479778; called by muse, mutect2, varscan2
- LRRC29 | c.-134-355_-134-351dup | Intron (INS) | VAF 96/239 reads (40%) | called by mutect2, pindel, varscan2
- MAML3 | c.468+18527C>T | Intron (SNP) | VAF 82/277 reads (30%) | catalogued as rs1052327437; called by muse, mutect2, varscan2
- ODF2L | chr1:86348892 G>T | 3'Flank (SNP) | VAF 39/103 reads (38%) | catalogued as COSV99644037; called by muse, mutect2, varscan2
- PDGFA | c.*33C>T | 3'UTR (SNP) | VAF 112/325 reads (34%) | catalogued as rs375939364; called by muse, mutect2, varscan2
- TK2 | c.31+134C>T | Intron (SNP) | VAF 171/236 reads (72%) | catalogued as COSV50451512; called by muse, mutect2, varscan2
